Somatic mutation profile of tumor specimen MP2PRT-PANUMR-TMP1-A (aliquot MP2PRT-PANUMR-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PANUMR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,426 days).
Specimen MP2PRT-PANUMR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4909273-c027-4ad6-9617-e22d7cbbd3ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PANUMR-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PANUMR-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/284cf8a9-2b56-4c45-a9c7-48288272ce10

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 2, Frame Shift Ins 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C11orf80 | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 274/623 reads (44%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs767063409; called by muse, mutect2, varscan2
- CD209 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 256/630 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs146082308, COSV52649682; called by muse, varscan2
- KDM4A | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 89/202 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769652752, COSV64960923; called by muse, mutect2, varscan2
- LRRC4C | c.986G>A p.R329Q | Missense Mutation (SNP) | VAF 185/411 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); catalogued as COSV53421587, COSV53424684; called by muse, mutect2, varscan2
- PLSCR4 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 148/367 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs768117831; called by muse, mutect2, varscan2
- TBKBP1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 201/492 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.022); catalogued as COSV64653807; called by muse, mutect2, varscan2
- DAB2IP | c.2121C>A p.N707K (on ENST00000408936; = p.N679K on NM_032552.3) | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ID2 | c.399del p.C133Wfs*4 | Frame Shift Del (DEL) | VAF 69/183 reads (38%) | called by pindel*, varscan2
- IKZF3 | c.522_523insTA p.K175* | Frame Shift Ins (INS) | VAF 85/253 reads (34%) | called by mutect2, pindel, varscan2
- PCCB | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 164/374 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.982); called by muse, varscan2
- SPI1 | c.187_188insGCTTC p.E63Gfs*125 | Frame Shift Ins (INS) | VAF 173/482 reads (36%) | called by mutect2, pindel, varscan2
- TGFB3 | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 152/309 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- ZNF483 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCF2L | c.3363C>A p.A1121= (on ENST00000375608; = p.A1089= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 383/880 reads (44%) | called by muse, mutect2, varscan2
- PBX1 | c.183G>A p.A61= | Silent (SNP) | VAF 56/370 reads (15%) | called by muse, mutect2, varscan2
- FAM53A | c.883-2620C>T | Intron (SNP) | VAF 135/301 reads (45%) | catalogued as rs563668707; called by muse, mutect2, varscan2
